TCGA case TCGA-QH-A6CW — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Fondazione-Besta. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe5c5c11-ef39-4907-9a70-67f37bb62fd7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Italy; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Mixed glioma: ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 43.4 years (15,847 days); Year of diagnosis: 2013; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 414 days (1.1 years); First symptom longest duration: 31-90 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.

Follow-up (3 entries)
- Day -8 (preoperative): Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: -1 day; Disease response: With Tumor.
- Days to follow up: 414 days (1.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- IDH1 mutation, nos (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.
- Timepoint category: Adulthood; Comorbidities: Allergies / Asthma; Risk factors: Asthma / Hay Fever / Allergy, Mold or Dust.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QH-A6CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 270 mg.
  Slide TCGA-QH-A6CW-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QH-A6CW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QH-A6CW-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 31 - 90 Days; History asthma: Yes; History eczema: No; Histor hay fever: Yes; History dust mold allergy: Yes; Asthma eczema allergy first diagnosis: > 20 Years; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Family history brain tumor: No; Idh1 mutation test indicator: Yes; Idh1 mutation found: Yes; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No; Treatment outcome at TCGA followup: Partial Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 414 days; disease-specific survival: no event (censored), 414 days; progression-free interval: no event (censored), 414 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QH-A6CW-01A-11D-A32A-01): tumor purity 0.87, ploidy 2.04, whole-genome doublings 0.
